Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8M8, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8M8-01A (Primary Tumor).

[page 1 of 3]
Operative Procedure:
Sternotomy, (illegible).

Pre-Operative Diagnosis:
Malignant neoplasm of thymus.

Specimen Received:
A: Thymoma (FS)
B: Mediastinum for flow only

Final Pathologic Diagnosis:
Anterior mediastinum, resection of mass:
Thymoma, WHO type B2 (see Note).
-confined to mediastinum without either gross or microscopic evidence of
invasive growth.
-one benign lymph node present adjacent to thymus.

The examination of this case material and the preparation of this report were
performed by the staff pathologist.

Note:

Sections through the specimen show thymoma, WHO type B2. The tumor appears
circumscribed without any microscopic evidence of invasive growth. Although
tumor cells are present within 1 to 2 mm of the inked surgical margin (tumor
surrounded by fibrous capsule), there is no evidence of tumor transection and,
thus, the tumor appears to have completely excised. Nonetheless, clinical
followup for potential recurrence is warranted.

Intraoperative Consult Diagnosis:

FSA: Thymus, partial resection:
Tumor present. Thymoma vs. lymphoma.
F/S TAT: 10 mins.

Gross Description:

The specimen is received fresh for frozen section evaluation and is additionally
labeled "thymoma (FSA+X)" and consists of an 8.5 x 6.5 x
3.3 cm irregular partially fragmented portion of yellow-tan to tan-brown fatty
fibrous tissue. The specimen is notable for a 5.8 x 3.4 x 2.8 cm nodular and
encapsulated gray-white mass. The mass abuts the inked outer membranous
surface. Sectioning reveals a white-tan fleshy cut surface with delicate
intervening gray-white septations. There are no areas of hemorrhage or necrosis.
The remainder of the uninvolved cut surface is yellow-tan and lobulated with
focal hemorrhage. There is one focus measuring 1.7 cm in greatest dimension
suspicious for a fatty replaced lymph node.

Representative sections as follows:

- 1 FSA resubmitted for permanent section;

ICD-O 3
Thymoma, type B2 NOS 8584/1
Site: ^{CLCE}Thymus C37.9
^{path}Anterior mediastinum C38.1
GJ 6/10/14

[page 2 of 3]
- 2 encapsulated tumor to inked outer surface;
- 3-4 tumor to adjacent fatty tissue/thymoma;
- 5 additional full thickness section of mass;
- 6-7 representative sections of adjacent fatty tissue;
- 8 possible fatty replaced lymph node.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

Procedures/Addenda:

Interpretation

Flow cytometric analysis of thymus shows a precursor T-cell population and mature T-cells. B cells are too few to assess clonality. Correlation with morphology is mandatory for final diagnosis.

Results-Comments

Gated cells represent 15% of total sample

ANTIBODY % POSITIVE CELLS IN LYMPHOID GATE

B-RELATED

CD19	<1
CD20	1
CD20+/CD5+	<1
CD10	17

CD19 positive population

CD19/Kappa	<1
CD19/Lambda	<1

T-RELATED

CD7	94
CD2	98
CD5	96
CD3	87
CD4	56
CD8	34

MYELOID/OTHER

CD34	1
CD34+/CD56+	<1
CD33	1
CD13	1
CD13+/CD7+	<1
CD15	<1
CD117	<1
CD15+/CD117+	<1

[page 3 of 3]
CD64	<1
CD14	4
CD11b	11
CD61	<1
CD56	4
HLA-DR	7
CD71	15
CD38	77
TdT	96

Viability: 92

Morphologic review of cytospin demonstrates numerous immature lymphoid cells.

END OF REPORT

Surgical Pathology Report

Taken: DOB: (Age: Gender: M

Source: NCI Genomic Data Commons file edef30fa-9d14-4dc5-b6f5-52bec1f9ea74 (TCGA-X7-A8M8.306EDAE4-F4E8-4705-8EDE-EF029EAA2F98.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).